National Lung Screening Trial (NLST) participant 200848 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 59 years; Gender: female; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 40 effective mAs, display field of view 25 cm, reconstruction filter Siemens B50F / Siemens B30.
- T1 (day 377): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 40 effective mAs, display field of view 24 cm, reconstruction filter Siemens B50F / Siemens B30.
- T2 (day 825): Positive, no significant change: stable abnormalities potentially related to lung cancer, unchanged since the prior screening exam. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 40 effective mAs, display field of view 24 cm, reconstruction filter Siemens B50F / Siemens B30.

Abnormalities recorded by the reading radiologist on the CT screens (29 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Other minor abnormality noted.
- T0 abnormality 2: Other minor abnormality noted.
- T0 abnormality 3: Emphysema.
- T0 abnormality 4: Pleural thickening or effusion.
- T0 abnormality 5: Benign lung nodule(s) (benign calcification).
- T0 abnormality 6: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T0 abnormality 7: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T0 abnormality 8: Other minor abnormality noted.
- T0 abnormality 9: Other minor abnormality noted.
- T1 abnormality 1: Other minor abnormality noted.
- T1 abnormality 2: Other minor abnormality noted.
- T1 abnormality 3: Pleural thickening or effusion.
- T1 abnormality 4: Emphysema.
- T1 abnormality 5: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T1 abnormality 6: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 7: Benign lung nodule(s) (benign calcification).
- T1 abnormality 8: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 4 mm, longest perpendicular diameter 3 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 80; pre-existing on earlier images (earliest visible day 0); interval growth; no suspicious change in attenuation.
- T1 abnormality 9: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 5 mm, longest perpendicular diameter 4 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 22; pre-existing on earlier images (earliest visible day 0); interval growth; no suspicious change in attenuation.
- T1 abnormality 10: Other minor abnormality noted.
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 4 mm, longest perpendicular diameter 3 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 73; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T2 abnormality 2: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 3: Benign lung nodule(s) (benign calcification).
- T2 abnormality 4: Pleural thickening or effusion.
- T2 abnormality 5: Emphysema.
- T2 abnormality 6: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T2 abnormality 7: Other minor abnormality noted.
- T2 abnormality 8: Other minor abnormality noted.
- T2 abnormality 9: Other minor abnormality noted.
- T2 abnormality 10: Other minor abnormality noted.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,007.
